Gene-level copy-number profile of tumor specimen TCGA-VN-A88K-01A from TCGA case TCGA-VN-A88K, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.9 years (21,524 days).
Specimen TCGA-VN-A88K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.2633fa71-27f3-4ac2-9d86-f3d058176db1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VN-A88K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83f2e617-0803-40d0-9d1b-d64229c97d9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 6,691; copy number 2: 48,905; copy number 3: 4,155.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VN-A88K-01A-11D-A34T-01): tumor purity 0.82, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,783,354–10,859,436, 52 genes (within-gene range 0–1): MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2.
- chr16:72,665,123–72,822,781, 4 genes: AC004943.2, RNU7-90P, KRT18P18, AC004943.3.
- chr16:72,805,998–73,016,016, 6 genes: AC004943.1, RNU7-71P, AC132068.1, AC002044.3, AC002044.1, AC002044.2.
- chr21:41,304,212–41,531,116, 5 genes (within-gene range 0–1): FAM3B, MX2, MX1, AP001610.2, TMPRSS2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
